Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAN2, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAN2-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

DIAGNOSIS:

RADICAL CYSTOPROSTATECTOMY, PELVIC LYMPH NODE DISSECTION, URINARY DIVERSION AND GASTROSTOMY TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT EXTERNAL ILIAC LYMPH NODE (C):

FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

URETHRAL MARGIN (D):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRA AND PERIURETHRAL TISSUE
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER/PROSTATE (E)

BLADDER:

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA WITH SQUAMOUS AND GLANDULAR FOCI (3 X 2.5 X 1.6 CM), GRADES 3 AND 4/4, EXTENDING INTO DEEP MUSCULARIS PROPRIA AND APPROACHING BUT NOT INVOLVING PERIVESICAL SOFT TISSUE
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- ADDITIONAL RANDOM MUCOSA INCLUDING TRIGONE/BLADDER NECK, NO UROTHELIAL DYSPLASIA OR CARCINOMA IN SITU (FLAT LESION) IDENTIFIED
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

PROSTATE:

- BILATERAL MODERATELY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 6 (3+3), CONFINED TO PROSTATE WITHOUT INVOLVEMENT OF CAPSULE OR PERIPROSTATIC SOFT TISSUE
- MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II AND III)
- PROSTATIC URETHRA, NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- BILATERAL SEMINAL VESICLES, FREE OF MALIGNANCY
- RESECTION MARGINS FREE OF MALIGNANCY AND UROTHELIAL DYSPLASIA

RIGHT PARACAVAL LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PARA-AORTIC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT COMMON ILIAC LYMPH NODES (H):

ICD-0-3

Carcinoma, urothelial NOS
8120/3

Site: Bladder NOS
C67.9

4/23/26/14

Pin TSS, glandular = 20%, Squamous = 20%.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT COMMON ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

ADDITIONAL RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT LYMPH NODE OF CLOQUET (K):

- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY SUBMITTED]

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN TWELVE LYMPH NODES EXAMINED (0/12)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN TEN LYMPH NODES EXAMINED (0/10)

LEFT LYMPH NODE OF CLOQUET (N):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN SEVENTEEN LYMPH NODES EXAMINED (0/17)

RIGHT PRESACRAL LYMPH NODES (P):

- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY SUBMITTED]

PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT PRESACRAL LYMPH NODES (R):

- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY SUBMITTED]

ADDITIONAL LEFT PARA-AORTIC LYMPH NODES (S):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT PROXIMAL URETER (T):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (U):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO MALIGNANCY IDENTIFIED IN TOTAL OF
EXAMINED (0/73) 73 LYMPH NODES

PATHOLOGIC TNM STAGE: BLADDER: pT2bN0MX PROSTATE: pT2bN0MX
(AJCC- 1997)

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

immunohistology, results of which will be issued in an addendum report.

SPECIMEN SOURCE:

- A: "Right distal ureter F/S"
- B: "Left distal ureter F/S"
- C: "Rt. external iliac lymph node"
- D: "Urethral margin"
- E: "Bladder/prostate"
- F: "Right para caval lymph nodes"
- G: "Left para aortic lymph nodes"
- H: "Right common iliac lymph nodes"
- I: "Left common iliac lymph nodes"
- J: "Additional right external iliac lymph nodes"
- K: "Right lymph node of cloquet"
- L: "Right obturator/hypogastric lymph nodes"
- M: "Left external iliac lymph nodes"
- N: "Left lymph node of cloquet"
- O: "Left obturator/hypogastric lymph nodes"
- P: "Rt. presciatic lymph nodes"
- Q: "Pre sacral lymph nodes"
- R: "Left pre sciatic lymph nodes"
- S: "Additional left para aortic lymph nodes"
- T: "Right proximal ureter"
- U: "Left proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder tumor

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter F/S". It consists of a single segment of ureter measuring 0.2 cm in length and 0.4 cm in diameter. The specimen is entirely submitted for frozen section diagnosis in AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S". It consists of a portion of ureter measuring 0.2 cm in length and 0.4 cm in diameter. The specimen is entirely submitted for frozen section diagnosis in BFS.

C: The specimen is received fresh from the O.R. and labeled "Rt. external iliac lymph node". It consists of two lymph nodes measuring in aggregate 1 x 0.5 x 0.3 cm. One lymph node is bivalved and the second one is left intact. Both lymph nodes are entirely submitted for frozen section diagnosis in CFS.

D: The specimen is received fresh from the O.R. and labeled "Urethral margin". It consists of one fragment of tan tissue measuring 1 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis in DFS.

E: The specimen is received fresh from the O.R. and labeled "Bladder/prostate". It consists of a radical cystoprostatectomy specimen measuring 29.5 x 11 x 3.4 cm. A flap of peritoneal fat is present measuring 27.5 x 11.6 by less than 0.1 cm. The peritoneal surface is smooth and glistening. The bladder itself measures 6.2 x 5 x 3.6 cm. The resection margin and prostate are inked black with red ink superimposed on the right side. The bladder is then opened along the anterior prostatic urethra and bladder wall. The uninvolved bladder wall measures 1.1 cm in thickness. Opening the bladder reveals an ulcerated mass lesion abutting the right ureterovesical junction. The lesion measures 3 x 2.5 x 1.6 cm. The mass extends into the deep muscle of the bladder wall but does not penetrate the surrounding soft tissue grossly. It extends into the ureterovesical junction over a distance

[page 4 of 6]
Collected
Ordered by

of 1.5 cm. No other lesion is identified and the remaining bladder mucosa appears grossly unremarkable. The attached ureters are identified and opened. The right ureter measures 10.9 cm in length and 1 cm in circumference. The left attached ureter measures 4.2 cm in length and 0.6 cm in circumference. Both ureters are grossly unremarkable except for the tumor involvement of the right UVJ previously mentioned. The prostate measures 5.3 x 3.2 x 2.6 cm. The left seminal vesicle measures 4 x 1.7 x 0.8 cm, and the right seminal vesicle measures 3.6 x 1.6 x 0.8 cm. The prostatic urethra measures 2.5 cm in length and 2.7 cm in circumference. There is no excavation present. The mucosal surface is pink-tan and grossly unremarkable. The verumontanum measures 1 x 0.5 x 0.2 cm. The prostate is serially sectioned. No discrete lesion is identified grossly. Representative sections are submitted in 23 cassettes.

F: The specimen is received in formalin and labeled "Right para caval lymph nodes". It consists of a segment of adipose tissue measuring 2 x 1 x 0.4 cm. Entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Left para aortic lymph nodes". It consists of a single segment of adipose tissue measuring 4.5 x 2 x 0.6 cm. Entirely submitted in two cassettes.

H: The specimen is received in formalin and labeled "Right common iliac lymph nodes". It consists of multiple fragments of adipose tissue measuring 3 x 2.6 x 0.6 cm in aggregate. Entirely submitted in two cassettes.

I: The specimen is received in formalin and labeled "Left common iliac lymph nodes". It consists of multiple fragments of adipose tissue measuring 5.5 x 4.6 x 1.2 cm in aggregate. Entirely submitted in four cassettes.

J: The specimen is received in formalin and labeled "Additional right external iliac lymph nodes". It consists of multiple fragments of adipose tissue measuring 10.4 x 5.6 x 1.5 cm in aggregate. Entirely submitted in eight cassettes.

K: The specimen is received in formalin and labeled "Right lymph node of cloquet". It consists of a single segment of adipose tissue measuring 1.2 x 0.5 x 0.4 cm. Entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "Right obturator/hypogastric lymph nodes". It consists of multiple fragments of adipose tissue measuring 8.5 x 4.6 x 1.6 cm in aggregate. Entirely submitted in eight cassettes.

M: The specimen is received in formalin and labeled "Left external iliac lymph nodes". It consists of multiple fragments of adipose tissue measuring 6.7 x 4.46 x 1.2 cm in aggregate. Entirely submitted in six cassettes.

N: The specimen is received in formalin and labeled "Left lymph node of cloquet". It consists of a single segment of adipose tissue measuring 1.6 x 1 x 0.4 cm. Entirely submitted in one cassette.

O: The specimen is received in formalin and labeled "Left obturator/hypogastric lymph nodes". It consists of multiple fragments of adipose tissue measuring 9.2 x 4.6 x 1.2 cm in aggregate. Entirely submitted in nine cassettes.

P: The specimen is received in formalin and labeled "Rt. presciatic lymph nodes". It consists of multiple fragments of adipose tissue measuring 3.1 x 1 x 0.9 cm in aggregate. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Pre sacral lymph nodes". It consists of multiple fragments of adipose tissue measuring 5.5 x 3 x 1.2 cm in aggregate. Entirely submitted in four cassettes.

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

R: The specimen is received in formalin and labeled "Left pre sciatic lymph nodes". It consists of multiple fragments of adipose tissue measuring 2.2 x 1.6 x 0.5 cm in aggregate. Entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Additional left para aortic lymph nodes". It consists of multiple fragments of adipose tissue measuring 2.5 x 2 x 1.6 cm in aggregate. Entirely submitted in three cassettes.

T: The specimen is received in formalin and labeled "Right proximal ureter". It consists of a portion of ureter measuring 1 cm in length and 0.9 cm in diameter. There are two metallic clips present. The clips are removed and the specimen is entirely submitted in one cassette.

U: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a portion of ureter measuring 0.9 cm in length and 0.4 cm in diameter. There are two metallic clips present. The clips are removed and the specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, right external iliac lymph node
DFS: urethral margin
E1: bladder/prostate; right ureterovesical junction and tumor
E2: tumor
E3,4: one tissue slice, bisected full thickness, showing tumor with inked margin
E5-7: tumor
E8: anterior bladder
E9: dome
E10: posterior bladder wall
E11: left lateral bladder wall
E12: left ureterovesical junction
E13: trigone and bladder neck
E14: right prostatic apex
E15: left prostatic apex
E16: right anterior mid prostate
E17: right posterior mid prostate
E18: left anterior mid prostate
E19: left posterior mid prostate
E20: right anterior proximal prostate
E21: right posterior proximal prostate
E22: left anterior proximal prostate
E23: left posterior proximal prostate
F: right paracaval lymph nodes - all embedded
G1,2: left para-aortic lymph nodes - all embedded
H1,2: right common iliac lymph nodes - all embedded
I1-4: left common iliac lymph nodes - all embedded
J1-8: additional right external iliac lymph nodes - all embedded
K: right lymph node of cloquet - all embedded
L1-8: right obturator/hypogastric lymph nodes - all embedded
M1-6: left external iliac lymph nodes - all embedded
N: left lymph node of cloquet - all embedded
O1-9: left obturator/hypogastric lymph nodes
P: right presciatic lymph nodes - all embedded
Q1-4: presacral lymph nodes - all embedded
R: left presciatic lymph nodes - all embedded
S1-3: additional left para-aortic lymph nodes - all embedded
T: right proximal ureter - all embedded

[page 6 of 6]
SURGICAL PATHOLOGY REPORTCollected
Ordered by

Location

U: left proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:

- no high grade atypia or tumor identified

BFS: Left distal ureter:

- no high grade atypia or tumor identified

CFS: Right external iliac lymph node:

- benign

DFS: Urethral margin:

- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-D: See final microscopic-diagnosis.

E: Sections of the bladder show high grade invasive urothelial carcinoma (E1-3, 5-7), grades 3 and 4/4, extending into the deep muscularis propria. The tumor approaches without involving perivesical soft tissue. Lymphovascular space invasion is not identified. Additional random sections of the bladder show no urothelial dysplasia or malignancy. All resection margins are free of both dysplasia and malignancy. Sections of the prostate show prostatic adenocarcinoma (E16,18,19,23), Gleason's score 6 (3+3). The tumor is confined to the prostate. There are multiple foci of high-grade prostatic intraepithelial neoplasia (PIN II and III) present. The seminal vesicles and all resection margins are free of malignancy and urothelial dysplasia.

F-U: See final microscopic -diagnosis.

Source: NCI Genomic Data Commons file 7456f466-4113-464b-ada8-631161449b75 (TCGA-XF-AAN2.00D2C4D3-B209-4B54-992D-54E8048415BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).